Gene-level copy-number profile of tumor specimen TCGA-50-5045-01A from TCGA case TCGA-50-5045, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 57.4 years (20,961 days).
Specimen TCGA-50-5045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7d1b998b-41a2-4347-b559-7863f5b98339.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5045-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c84c2d8a-f5bb-4997-a828-280826bf38d7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,052; copy number 1: 4,199; copy number 2: 22,541; copy number 3: 22,505; copy number 4: 5,825; copy number 5: 1,369; copy number 6: 1,786; copy number 7: 49; copy number 8: 216; copy number 9: 524; copy number 10: 13; copy number 12: 40; copy number 13: 107.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5045-01A-01D-1624-01): tumor purity 0.22, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:106,815,197–107,011,052, 1 gene (within-gene range 0–1): LINC01950.
- chr10:80,776,165–80,778,088, 1 gene: FARSBP1.
- chr11:33,039,417–33,162,371, 4 genes (within-gene range 0–2): TCP11L1, PIGCP1, LINC00294, CSTF3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 949 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes, copy number 13 (within-gene range 2–13): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:58,198–45,895,970, 710 genes, copy number 8–12 (broad region; genes not listed).
- chr8:6,780,874–6,789,021, 1 gene, copy number 8 (within-gene range 1–8): AF233439.2.
- chr9:60,914,407–68,330,626, 169 genes, copy number 9–13 (broad region; genes not listed).
- chr9:68,353,614–68,357,893, 1 gene, copy number 13: PGM5-AS1.
- chr10:133,430,394–133,642,894, 13 genes, copy number 10: OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2.
- chr18:14,057,457–14,132,490, 1 gene, copy number 7 (within-gene range 4–7): ZNF519.
- chr18:14,104,542–15,330,282, 48 genes, copy number 7: AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 3,743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
